Gene-level copy-number profile of tumor specimen ALCH-ADAD-TTP1-A from ALCHEMIST case ALCH-ADAD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.7 years (21,447 days).
Specimen ALCH-ADAD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a1b1e6ba-943c-47c6-9341-be547849a03b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADAD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/d9b704ea-d529-49be-a481-26127e0c5740

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 8,628; copy number 2: 49,176; copy number 3: 450; copy number 4: 82; copy number 5: 1; copy number 6: 1; copy number 7: 1; copy number 69: 1.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:182,062,677–182,069,253, 1 gene: AL355482.1.
- chr3:50,558,025–50,596,168, 2 genes: C3orf18, HEMK1.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr10:92,418,667–92,420,875, 1 gene: MARK2P9.
- chr10:133,257,144–133,276,868, 2 genes: AL592071.1, ADAM8.
- chr11:2,159,779–2,161,221, 1 gene (within-gene range 0–2): INS.
- chr15:25,169,337–25,250,940, 45 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:85,754,941–85,794,925, 4 genes: LINC02883, KLHL25, MIR1276, AC021739.1.
- chr17:42,667,914–42,683,917, 3 genes (within-gene range 0–2): PLEKHH3, CCR10, AC100793.2.
- chr22:38,424,288–38,427,336, 1 gene (within-gene range 0–2): Z97056.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:917,287–921,005, 1 gene, copy number 6: KISS1R.
- chr21:43,414,483–43,427,131, 1 gene, copy number 5: SIK1.
- chr21:43,461,960–43,479,534, 1 gene, copy number 69 (within-gene range 2–69): LINC00313.
- chr22:18,906,028–18,914,238, 1 gene, copy number 7 (within-gene range 1–7): DGCR6.

Autosomal genes at a single copy (total copy number 1): 8,605. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
